CCDI case PBCLET — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/76808297-4413-423b-842b-47d48118a8b9

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Schwannoma, NOS: ICD-O-3 morphology code: 9560/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,835 days).

Biospecimens (3 samples)
- Sample 0DUETO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUEU9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUEUD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
